Surgical pathology report (de-identified scan), TCGA case TCGA-CE-A481, project TCGA-THCA (Thyroid Carcinoma), tissue source site ILSBio, specimen TCGA-CE-A481-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report (For Collection of Cancerous Tissue)

ICD-O-3
carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS C73.9

by 9/26/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status		Race
	1m 58	☐ Single ☒ Married ☐ Divorced ☐ Widow		Blood Pressure 117
Gender	Weight			Heart Rate
☐ Male ☒ Female	57kg			

HISTORY OF PRESENT ILLNESS
Chief Complaints: Vocal change; fever.
Symptoms: Fatigue.
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS					
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)	
				/ / To	/ /
				/ / To	/ /
				/ / To	/ /
				/ / To	/ /
				/ / To	/ /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☒ Pre-menopausal	years old	02
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		02
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers: _____						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy	carcinoma	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging	Date of Diagnosis	
T 1 N 0 M 0 Stage: I		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
resection of the tumour			
Primary Tumor			
Organ	Detailed Location	Size	
left thyroid tumour	left	4.5 x 1 x 1 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T 1 N 0 M 0 Stage: I			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____
Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)					
Frozen		Paraffin Block		Blood/Serum/Plasma	
Diseased	Normal	Diseased	Normal	Diseased	Normal
2	2	2	2		
Time to LN2		Time to Formalin		Time to LN2	
10 min		11 min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Thyroid Tumor	1.5 x 1 x 1 cm	Left	2 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT1 N0 M0		Stage: I	
Notes:			

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		☒	Streaming		
Mosaic	☒		Storiform		
Necrosis	☒	☒	Fibrosis		
Lymphocytic Infiltration		☒	Palisading		
Vascular Invasion		☒	Cystic Degeneration		
Clusterized	☒		Bleeding		
Alveolar Formation		☒	Myxoid Change		
Indian File		☒	Psammoma/Calcification	☒	

2. Cellular features:

Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamoid Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	☒		Fibroblast			Small Cell		
Keratin			Secretion	☒		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	☒		Lipoblast			Inflam. Cell		
Pearl			Gland formation	☒		Myoblast			Plasma Cell		
Otherwise Specified: D1 70% D2 30%											

2. Cellular Differentiation:

Well	Moderately	Poor
☒		

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis		☒		
Hyperchromatism		☒		
Nucleolar Prominent		☒		
Multinucleated Giant Cell		☒		
Mitotic Activity		☒		
Nuclear Grade				

Histological Diagnosis: Papillary Thyroid Carcinoma, G1

Comments: _____

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Reviewed by:	KM1	8/30/12

Source: NCI Genomic Data Commons file c7fed5aa-afd8-44e0-9aaf-10b3e30b14f9 (TCGA-CE-A481.519EA683-0FCE-4DBF-A103-AE7EC565D237.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).